Gene-level copy-number profile of tumor specimen AP-5JDU-VM from APOLLO case AP-5JDU, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Solid carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G3.
Specimen AP-5JDU-VM: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 22b422a2-ebc7-4b87-bccf-f2df4338e2fa.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-5JDU-W4 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/23e22c30-50a4-4a67-9bd7-78e3e2b8db4a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 56; copy number 1: 10,813; copy number 2: 46,894; copy number 3: 470; copy number 4: 120; copy number 5: 44.

Homozygous deletions (total copy number 0; autosomes only): 56 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,524,307–26,118,408, 40 genes (within-gene range 0–1): SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL365204.1, AL365204.2, AL365204.3, IZUMO3, AL353811.1, RMRPP5, RN7SKP120, TUSC1, LINC01241, FAM71BP1, AL353753.1.
- chr9:60,914,407–61,662,690, 16 genes: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA, AL935212.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 44 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:39,480,412–39,555,356, 8 genes, copy number 5: TIMM50, DLL3, SELENOV, EID2B, AC011500.3, TDGF1P7, EID2, AC011500.2.
- chr19:41,114,432–41,353,922, 12 genes, copy number 5 (within-gene range 2–5): CYP2F1, CYP2T3P, RPL36P16, RN7SL718P, CYP2S1, AXL, AC011510.1, HNRNPUL1, RN7SL34P, TGFB1, AC011462.5, CCDC97.
- chr19:41,350,911–41,384,083, 2 genes, copy number 5 (within-gene range 2–5): TMEM91, B9D2.
- chr19:41,998,321–42,390,297, 20 genes, copy number 5: GRIK5, ZNF574, POU2F2, AC010247.1, MIR4323, AC010247.2, DEDD2, AC006486.3, ZNF526, GSK3A, AC006486.1, AC006486.2, ERF, CIC, PAFAH1B3, PRR19, TMEM145, MEGF8, MIR8077, CNFN.
- chr19:42,401,514–42,427,388, 2 genes, copy number 5 (within-gene range 1–5): LIPE, AC011497.1.

Autosomal genes at a single copy (total copy number 1): 10,813. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
